Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7058, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7058-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass s/p IR biopsy that demonstrated high grade, renal cell carcinoma.

Specimens Submitted:

1: MESENTARY, OVERLYING RIGHT RENAL TUMOR; BIOPSY

2: GEROTA'S FASCIA, ANTERIOR; BIOPSY

3: KIDNEY, LOWER POLE AND CAVAL LYMPH NODES, PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. MESENTARY, OVERLYING RIGHT RENAL TUMOR; BIOPSY:

-Benign fibrofatty tissue

2. GEROTA'S FASCIA, ANTERIOR; BIOPSY:

-Benign fibrofatty tissue

3. KIDNEY, LOWER POLE AND CAVAL LYMPH NODES, PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Unclassified type

High grade. See comment

Tumor Size:

Greatest diameter is 4.2 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

however, tumor involves muscular branches of the renal vein

Surgical Margins:

Tumor present at renal parenchymal margin (for partial nephrectomy specimens only)

Non-Neoplastic Kidney:

Chronic nephritis, mild arteriolonephrosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Number of metastatic nodes:3

Number of nodes examined:8

The largest metastatic deposit measures 1cm and occupies the entire lymph node. Extranodal extension is absent. The majority of the metastatic tumor is necrotic.

[page 2 of 3]
[REDACTED]

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

Comment: This high grade tumor has features seen in both distal nephron (collecting duct) and "type 2" papillary renal carcinoma. It is immunoreactive for racemase but not CK7, CEA or 34BE12.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	PAS	
	34BE12	
	CK7	
	RACEMASE	
	CEA M	
	IMM RECUT	
	NEG CONT	
	RECUT	

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation, labeled "mesentery overlying right anterior kidney tumor" and consists of a 1.2 x 0.3 x 0.3 cm fragment of fatty tissue. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

[REDACTED]

2). The specimen is received fresh for frozen section consultation, labeled "Anterior Gerota's fascia" and consists of a 0.8 x 0.5 x 0.3 cm portion of fibrofatty tissue. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

[REDACTED]

3) The specimen is received fresh and is labeled "right lower pole kidney tumor and perinephric fat, paracaval lymph nodes". It consists of a 5.8 x 5.5 x 3.2 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a heterogeneous yellow/tan to white mass with areas of necrosis and hemorrhage that measures 4.2 x 3.5 x 2.4 cm and focally abuts the inked surgical margin and extends into the perinephric fat. All identified lymph nodes are submitted. Representatively submitted Portions of the tumor are submitted for TPS and photos are taken

Summary of sections:

T - tumor

M - margin

RS - representative sections

LLN - largest node

BLN - bisected node

[page 3 of 3]
LN – lymph nodes

Summary of Sections:

Part 1: MESENTARY, OVERLYING RIGHT RENAL TUMOR; BIOPSY

Block	Sect. Site	PCs
1	fsc	1

Part 2: GEROTA'S FASCIA, ANTERIOR; BIOPSY

Block	Sect. Site	PCs
1	fsc	1

Part 3: KIDNEY, LOWER POLE AND CAVAL LYMPH NODES, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	BLN	1
2	LLN	2
1	LN	1
8	M	8
2	RS	2
6	T	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: MESENTERY OVERLYING RIGHT ANTERIOR KIDNEY TUMOR
BENIGN FIBROUS TISSUE
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: SP: ANTERIOR GEROTA FASCIA
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 6aeddc22-5022-4dc5-baf1-67ddb2b27350 (TCGA-BQ-7058.4D1BDB18-B2F4-4B97-9FD8-B600C193E185.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).